Somatic mutation profile of tumor specimen 0DJXPS from CCDI case PBBXKP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 6.2 years (2,253 days).
Specimen 0DJXPS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8042380-4fc2-45ea-ae5e-018d432d7487.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJXRL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/203cb726-b319-49c7-bbec-11ee87a4df22

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF21A | c.4894A>T p.I1632L (on ENST00000361418 / NM_001378440.1; = p.I1619L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 201/470 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs148144546, COSV62771755; called by muse, mutect2, varscan2
- PCLAF | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 174/485 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs140686158; called by muse, mutect2, varscan2
- POM121 | c.3451G>A p.A1151T (on ENST00000434423; = p.A886T on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/914 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782587401, COSV99988306; called by muse, mutect2
- ACTR2 | c.1173G>T p.V391= | Silent (SNP) | VAF 224/608 reads (37%) | catalogued as COSV53199991; called by muse, mutect2, varscan2
- CPT1A | c.1437G>A p.P479= | Silent (SNP) | VAF 378/900 reads (42%) | catalogued as rs554525176; ClinVar: likely benign; called by muse, mutect2, varscan2
- TPP1 | c.229+91C>A | Intron (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
